Somatic mutation profile of tumor specimen TCGA-EI-6507-01A (aliquot TCGA-EI-6507-01A-11D-1733-10) from TCGA case TCGA-EI-6507, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.7 years (22,176 days).
Specimen TCGA-EI-6507-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85588a58-0c7e-4917-b777-7fdd25c38bdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6507-10A (Blood Derived Normal), aliquot TCGA-EI-6507-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23b542b3-6fcf-42dd-b59c-55d99e315218

The open-access MAF lists 1,147 somatic variants for this specimen: 885 protein-altering or splice-affecting, 244 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 608, Silent 244, Frame Shift Del 172, Frame Shift Ins 46, Nonsense Mutation 27, Splice Site 13, Splice Region 10, Intron 8, In Frame Del 7, RNA 4, 3'Flank 3, 3'UTR 2.

Variants (750 of 1,147; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CLCN1 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80356700, CM121976, CM930139, COSV100577570; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.179T>G p.M60R | Missense Mutation (SNP) | VAF 62/147 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV57247351, COSV57256248; called by muse, mutect2, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 61/254 reads (24%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 37/76 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 15/29 reads (52%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, varscan2
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, mutect2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.479C>T p.A160V (on ENST00000614293; = p.A130V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV55801163; called by muse, mutect2, varscan2
- ABCC2 | c.2548G>T p.A850S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV64986171; called by muse, mutect2, varscan2
- AC023055.1 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.911); catalogued as COSV60243276; called by muse, mutect2, varscan2
- ACACB | c.7373C>T p.T2458I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); catalogued as COSV58134544; called by muse, mutect2, varscan2
- ACIN1 | c.2809G>T p.E937* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV52976209; called by muse, mutect2, varscan2
- ACTN1 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as rs995103995, COSV51991746; called by muse, mutect2, varscan2
- ACTR3 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs200071930, COSV99603263; called by muse, mutect2, varscan2
- ACTR3B | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 144/578 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); catalogued as rs1415740149, COSV55448975; called by muse, mutect2, varscan2
- ACVR2A | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54029619; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 50/98 reads (51%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM19 | c.2526dup p.A843Rfs*81 (on ENST00000517905; = p.A843Rfs*73 on NM_033274.5) | Frame Shift Ins (INS) | VAF 12/55 reads (22%) | catalogued as rs769171707; called by mutect2, pindel, varscan2
- ADAM30 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as rs144018958, COSV65561080; called by muse, mutect2, varscan2
- ADARB2 | c.1930G>T p.G644C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV67182185; called by muse, mutect2, varscan2
- ADCY2 | c.2713G>A p.V905M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs368187458; called by muse, mutect2, varscan2
- ADCY7 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54266811, COSV54270760; called by muse, mutect2, varscan2
- ADGRF3 | c.1442C>T p.A481V (on ENST00000311519 / NM_001145168.1; = p.A282V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs970569253, COSV61049442; called by muse, mutect2, varscan2
- ADGRV1 | c.15057T>A p.D5019E | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV101315441, COSV67985134; called by muse, mutect2, varscan2
- ADPRHL1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.297); catalogued as rs761645929, COSV100733316; called by mutect2, varscan2
- ADRM1 | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV53360071; called by muse, mutect2, varscan2
- AFAP1L1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as rs1363930427, COSV57045230; called by muse, mutect2, varscan2
- AFDN | c.4637A>G p.K1546R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); catalogued as COSV60044544; called by muse, mutect2, varscan2
- AGBL2 | c.2037G>T p.E679D | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100101023; called by muse, mutect2, varscan2
- AKIRIN2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs753802898, COSV57636526; called by muse, mutect2, varscan2
- ALDH1L1 | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1448357393, COSV99856332; called by muse, mutect2, varscan2
- ALKBH6 | c.385C>A p.L129M (on ENST00000252984 / NM_001297701.2; = p.L157M on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99430725; called by muse, mutect2, varscan2
- ALOX12B | c.1018del p.L340Sfs*12 | Frame Shift Del (DEL) | VAF 42/162 reads (26%) | catalogued as COSV100047960; called by mutect2, pindel, varscan2
- ALPG | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs375144819, COSV54966589; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 47/153 reads (31%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ANKEF1 | c.2326A>C p.T776P | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as COSV101000959; called by muse, mutect2, varscan2
- ANKMY1 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs141510821, COSV56033999; called by muse, mutect2, varscan2
- ANKRD45 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as COSV100322335; called by muse, mutect2, varscan2
- ANTXR2 | c.1316C>A p.P439H | Missense Mutation (SNP) | VAF 124/490 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as COSV56315438; called by muse, mutect2, varscan2
- AP5Z1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs761542147, COSV62241767; called by muse, varscan2
- APBB1 | c.1802T>C p.L601P | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54968123; called by muse, mutect2, varscan2
- APEH | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV56533711; called by muse, mutect2, varscan2
- APEX2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs749036434, COSV66623956; called by muse, mutect2, varscan2
- APOBEC3G | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs552054727, COSV68470300; called by muse, mutect2, varscan2
- APOL1 | c.668T>C p.I223T | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as COSV59868984; called by muse, mutect2, varscan2
- AR | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); catalogued as COSV65957007; called by muse, mutect2, varscan2
- ARAP1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.117); catalogued as COSV61991149; called by muse, mutect2, varscan2
- ARAP2 | c.4766G>T p.R1589M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV58286693; called by muse, mutect2, varscan2
- ARHGAP11A | c.2780C>G p.S927C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100276625, COSV100277020; called by muse, mutect2, varscan2
- ARID1B | c.5887G>A p.G1963R | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV51661612, COSV51666752; called by muse, mutect2, varscan2
- ARID5B | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.035); catalogued as COSV54420475; called by muse, mutect2, varscan2
- ARSA | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV53350452; called by muse, mutect2, varscan2
- ASB1 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV52827009; called by muse, mutect2, varscan2
- ASB14 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV67467190, COSV67467249; called by muse, mutect2
- ASIC3 | c.980A>G p.K327R | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV99876546; called by muse, mutect2, varscan2
- ATAD2B | c.4246G>A p.A1416T | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV53198618; called by muse, mutect2, varscan2
- ATAT1 | c.1144A>G p.M382V (on ENST00000376485; = p.M370V on NM_001031722.4) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1016436857, COSV53314009; called by muse, mutect2, varscan2
- ATG10 | c.72A>T p.Q24H | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV56426016, COSV56431322; called by muse, mutect2, varscan2
- ATG10 | c.216+2T>C p.X72_splice | Splice Site (SNP) | VAF 69/238 reads (29%) | catalogued as COSV99966462; called by muse, mutect2, varscan2
- ATG9A | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.353); catalogued as rs781020199, COSV54695890; called by muse, mutect2, varscan2
- ATG9B | c.293del p.P98Qfs*8 | Frame Shift Del (DEL) | VAF 45/149 reads (30%) | catalogued as rs770350293; called by mutect2, varscan2
- ATG9B | c.27del p.R10Efs*96 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as rs760721903; called by mutect2, varscan2
- ATXN2L | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100295046, COSV57370303; called by muse, mutect2, varscan2
- B4GALT3 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs367870203, COSV60527194; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 21/90 reads (23%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BAP1 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1451498951, COSV56232501; called by muse, mutect2, varscan2
- BCL6B | c.1326C>T p.C442= | Splice Region (SNP) | VAF 10/31 reads (32%) | catalogued as rs1175388791, COSV53427821; called by muse, mutect2, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs751794665; called by mutect2, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs756382429; called by mutect2, pindel, varscan2
- BCL9L | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52682435; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 18/37 reads (49%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BDH1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs200605471, COSV100827263, COSV64018493; called by muse, mutect2, varscan2
- BIRC2 | c.1622T>C p.V541A | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as COSV57161431; called by muse, mutect2, varscan2
- BMPER | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs368059451, COSV99778958; called by muse, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 25/122 reads (20%) | catalogued as rs751941533; called by mutect2, pindel, varscan2
- BPIFA2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1290925617, COSV53611027; called by muse, mutect2, varscan2
- BRCA2 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV101203800; called by muse, mutect2, varscan2
- BSN | c.5069C>T p.A1690V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56517840; called by muse, mutect2, varscan2
- C11orf80 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs771347098, COSV60929254, COSV60931469; called by muse, mutect2, varscan2
- C12orf42 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1210676786, COSV59382780; called by muse, mutect2, varscan2
- C1QTNF9B | c.327G>T p.M109I | Missense Mutation (SNP) | VAF 53/460 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV101158515, COSV65944158; called by muse, mutect2, varscan2
- C1orf226 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as COSV63395327; called by muse, mutect2, varscan2
- C22orf42 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 131/526 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV66075877; called by muse, mutect2, varscan2
- C2orf16 | c.1015T>C p.S339P | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs763049275, COSV68646069; called by muse, mutect2, varscan2
- C5orf34 | c.413G>T p.R138I | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV60930134; called by muse, mutect2, varscan2
- C9orf72 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs774440971, COSV101186471; called by muse, mutect2, varscan2
- CACHD1 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV51553197; called by muse, mutect2, varscan2
- CACNA1A | c.5914C>T p.R1972W | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1269205597, COSV64189270, COSV64204941; called by muse, mutect2, varscan2
- CALHM1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs368218776, COSV61707562; called by muse, mutect2, varscan2
- CAPN15 | c.925C>A p.R309S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.029); catalogued as COSV54835939; called by muse, mutect2, varscan2
- CAPN3 | c.1988_1990del p.G663del | In Frame Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs770529441; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel
- CARNS1 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs776913935, COSV57049877; called by muse, mutect2, varscan2
- CATSPER3 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50946383; called by muse, mutect2, varscan2
- CBY2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs761413589, COSV60117619; called by muse, mutect2, varscan2
- CCAR2 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs948374385, COSV57905536; called by muse, mutect2, varscan2
- CCDC151 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.052); catalogued as COSV99371200; called by muse, mutect2
- CCDC153 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.209); catalogued as rs563015042, COSV59539935; called by muse, mutect2, varscan2
- CCDC184 | c.190del p.A64Pfs*30 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs750406248; called by mutect2, pindel, varscan2
- CCDC82 | c.1380G>T p.Q460H | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53593431; called by muse, varscan2
- CCDC82 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202142231, COSV53593442; called by muse, varscan2
- CCDC88A | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 76/345 reads (22%) | catalogued as COSV55061573; called by muse, mutect2, varscan2
- CCIN | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV58724655; called by muse, mutect2, varscan2
- CCKBR | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV58101424; called by muse, mutect2, varscan2
- CD163L1 | c.1411A>G p.K471E | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV58016046; called by muse, mutect2, varscan2
- CDH9 | c.525T>C p.G175= | Splice Region (SNP) | VAF 33/126 reads (26%) | catalogued as COSV99141135; called by muse, mutect2, varscan2
- CDHR1 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs773335171, COSV60560277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDHR4 | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV58526160; called by muse, mutect2, varscan2
- CELA3A | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs1470126612, COSV51583416, COSV51585978; called by muse, mutect2, varscan2
- CELF3 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs750118563, COSV51883400; called by muse, varscan2
- CELF4 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610827, COSV58469327; called by muse, mutect2, varscan2
- CELSR3 | c.2777C>T p.T926I | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99372148; called by muse, mutect2, varscan2
- CENPT | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs1157489139, COSV54649770; called by muse, mutect2, varscan2
- CEP128 | c.2997T>A p.Y999* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV55376656; called by muse, mutect2, varscan2
- CFAP100 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs371120376, COSV61503123; called by muse, mutect2, varscan2
- CFAP46 | c.7622C>T p.A2541V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); catalogued as rs143790683, COSV54155598; called by muse, mutect2, varscan2
- CFTR | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as CM930112, COSV99133550; called by muse, mutect2, varscan2
- CHAC1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV101471072, COSV71436079; called by muse, mutect2, varscan2
- CHRNG | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as rs750265817, COSV67315562; called by muse, mutect2, varscan2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as rs745406065; called by pindel, varscan2
- CILP2 | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV52274963; called by muse, mutect2
- CLDN25 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as COSV71620437, COSV71620483; called by muse, mutect2, varscan2
- CLDN25 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs187854554, COSV71620438; called by muse, mutect2, varscan2
- CLTC | c.4375A>G p.N1459D | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV52247703; called by muse, mutect2, varscan2
- CMTM5 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV59305863; called by muse, mutect2, varscan2
- COBL | c.3656C>A p.A1219E | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV54345796; called by muse, mutect2, varscan2
- COG3 | c.1790_1791del p.E597Vfs*10 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as rs1454932535; called by pindel, varscan2
- COL11A1 | c.2435C>A p.P812H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100614357; called by muse, mutect2, varscan2
- COL17A1 | c.3973G>A p.G1325S | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.148); catalogued as rs767927119, COSV59825463; called by muse, mutect2, varscan2
- COL21A1 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.251); catalogued as COSV55162589; called by muse, mutect2, varscan2
- COL27A1 | c.3191G>A p.R1064H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs368823650; called by muse, mutect2, varscan2
- COL4A1 | c.2951G>A p.G984E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65425625; called by muse, mutect2, varscan2
- COL6A2 | c.1336del p.X446_splice | Splice Site (DEL) | VAF 35/182 reads (19%) | catalogued as rs1168245071; called by mutect2, pindel, varscan2
- COL9A1 | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.472); catalogued as COSV100293626; called by muse, mutect2, varscan2
- COQ6 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV53178743; called by muse, mutect2, varscan2
- COX4I2 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101064158; called by muse, mutect2, varscan2
- CPEB4 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 47/186 reads (25%) | catalogued as COSV54170869; called by muse, mutect2, varscan2
- CPLANE1 | c.*2911G>T | Splice Region (SNP) | VAF 17/136 reads (13%) | catalogued as COSV57071580, COSV99949231; called by muse, mutect2, varscan2
- CREBBP | c.3775C>T p.Q1259* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV52123780; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 84/288 reads (29%) | catalogued as rs1378599948; called by mutect2, varscan2
- CRHR1 | c.334del p.S112Afs*92 (on ENST00000398285 / NM_001145146.2; = p.S112Afs*63 on NM_004382.5) | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | catalogued as rs746467817; called by mutect2, pindel, varscan2
- CROCC | c.2962C>T p.R988W | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs3969856, COSV65012030; called by muse, mutect2, varscan2
- CSF3 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.037); catalogued as rs190847104; called by muse, mutect2, varscan2
- CSMD1 | c.4208G>A p.R1403H (on ENST00000520002; = p.R1402H on NM_033225.6) | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758153692, COSV59277963; called by muse, mutect2, varscan2
- CST5 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs756477706, COSV59014459; called by muse, mutect2, varscan2
- CTNND1 | c.420G>A p.T140= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100650268, COSV62383463; called by muse, mutect2, varscan2
- CUX1 | c.1289del p.P430Lfs*27 | Frame Shift Del (DEL) | VAF 26/132 reads (20%) | catalogued as rs782381199; called by pindel, varscan2
- CYB5R3 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100677744; called by mutect2, varscan2
- CYP2B6 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100137222; called by muse, mutect2, varscan2
- CYP2W1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs1050340285, COSV100417058; called by muse, mutect2, varscan2
- DBN1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as rs144418852; called by muse, mutect2, varscan2
- DCAKD | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100149382; called by muse, mutect2, varscan2
- DCC | c.1771T>A p.F591I | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100497380; called by muse, mutect2, varscan2
- DDHD2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs767497993, COSV68157865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX31 | c.1997A>G p.D666G | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); catalogued as COSV64649527; called by muse, mutect2, varscan2
- DEDD2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs781250383, COSV60140880; called by muse, mutect2, varscan2
- DHX32 | c.1877T>C p.M626T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs1213636050, COSV52940189; called by muse, mutect2, varscan2
- DHX8 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs770990323, COSV52253345, COSV99292550; called by muse, mutect2, varscan2
- DICER1 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs750410087, COSV58619861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DKK3 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.06); catalogued as COSV58868668; called by muse, mutect2
- DLAT | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs782767621, COSV54770737; called by muse, mutect2, varscan2
- DLGAP2 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as rs762702813, COSV70098169; called by muse, mutect2, varscan2
- DNAH11 | c.10610T>C p.V3537A | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100176112; called by muse, mutect2, varscan2
- DNAH17 | c.8939C>T p.P2980L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs374923749, COSV67751791; called by muse, mutect2, varscan2
- DNAH5 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs1160013087, COSV54224506; called by muse, mutect2, varscan2
- DNAH7 | c.10793T>A p.L3598Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56764846; called by muse, mutect2, varscan2
- DNAH9 | c.13094G>A p.R4365H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs368954907; called by muse, mutect2, varscan2
- DNAI4 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 98/384 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV64018576; called by muse, mutect2, varscan2
- DOCK5 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs994166763, COSV52406662; called by muse, mutect2, varscan2
- DOCK7 | c.6258T>A p.D2086E (on ENST00000635253 / NM_001367561.1; = p.D2055E on NM_033407.3) | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV52005463; called by muse, mutect2, varscan2
- DOCK9 | c.5154G>T p.E1718D (on ENST00000376460 / NM_001366676.2; = p.E1719D on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV59629304; called by muse, mutect2, varscan2
- DPP10 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs1055873408, COSV59686211; called by muse, mutect2, varscan2
- DPP3 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.576); catalogued as COSV57856830; called by muse, mutect2, varscan2
- DPP6 | c.505A>G p.N169D (on ENST00000377770 / NM_001364500.2; = p.N107D on NM_001936.5) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV59613181; called by muse, mutect2, varscan2
- DPP6 | c.1172G>A p.S391N (on ENST00000377770 / NM_001364500.2; = p.S329N on NM_001936.5) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.06); catalogued as COSV59613206; called by muse, mutect2, varscan2
- DPRX | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64949467; called by muse, mutect2, varscan2
- DPYD | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64597605, COSV64597766; called by muse, mutect2, varscan2
- DPYSL4 | c.885G>T p.W295C | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58307374; called by muse, mutect2, varscan2
- DRAP1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.11); catalogued as rs143922438; called by muse, mutect2, varscan2
- DTX3L | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.123); catalogued as COSV56144131; called by muse, mutect2, varscan2
- DUOX1 | c.4639C>T p.H1547Y | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV52050510; called by muse, mutect2, varscan2
- DUSP22 | c.41T>G p.I14S | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100739285; called by muse, mutect2
- E2F7 | c.2318G>A p.G773D | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs770738170, COSV59739950; called by muse, mutect2, varscan2
- EBI3 | c.593G>T p.R198M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV99695997; called by muse, mutect2, varscan2
- EDIL3 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56897132, COSV56908142; called by muse, mutect2, varscan2
- EFEMP2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as rs773352910, COSV57260119; called by muse, mutect2, varscan2
- EFL1 | c.3248C>A p.S1083Y | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.496); catalogued as COSV51605524; called by muse, mutect2, varscan2
- EFNA4 | c.535del p.D179Tfs*15 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | catalogued as rs754580525; called by mutect2, pindel, varscan2
- EGF | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99490281; called by muse, mutect2, varscan2
- EGFL8 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as rs371176366; called by muse, mutect2, varscan2
- EHD1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.172); catalogued as COSV100276774; called by muse, mutect2
- EHMT1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58374904; called by muse, mutect2, varscan2
- ELMO1 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs747396168, COSV60304648; called by muse, mutect2, varscan2
- ENPP3 | c.1213del p.R405Afs*36 | Frame Shift Del (DEL) | VAF 31/131 reads (24%) | catalogued as COSV62954163; called by mutect2, pindel, varscan2
- EPHA10 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV57623988; called by muse, varscan2
- EPHA4 | c.907G>T p.G303* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV56032888; called by muse, mutect2, varscan2
- EPHB1 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV67661558; called by muse, mutect2, varscan2
- EPHB6 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs56021232, COSV63891737; called by muse, mutect2, varscan2
- EPYC | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs745867926, COSV53798426, COSV53800078; called by muse, mutect2, varscan2
- ERCC6L | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0.049); catalogued as rs746565139, COSV57819632; called by muse, mutect2, varscan2
- ERGIC1 | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV58595744; called by muse, mutect2, varscan2
- ESR1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52787218, COSV52790758, COSV52803182; called by muse, mutect2, varscan2
- ESRRA | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as COSV50005540; called by muse, mutect2, varscan2
- ESRRB | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV55061501; called by muse, mutect2, varscan2
- ETV2 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV100981263; called by muse, mutect2, varscan2
- EWSR1 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV58423636; called by muse, mutect2, varscan2
- EXOC6B | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs756368454, COSV55555100; called by muse, mutect2, varscan2
- EXOC8 | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV50478216; called by muse, mutect2, varscan2
- EXT2 | c.803A>G p.D268G (on ENST00000343631; = p.D301G on NM_000401.3) | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV59150015; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 34/117 reads (29%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel, varscan2
- FAM71E1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs745613786, COSV58541644; called by muse, mutect2, varscan2
- FAM98C | c.860G>A p.C287Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53038865; called by muse, mutect2, varscan2
- FARP2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs555590124, COSV50871321; called by muse, mutect2, varscan2
- FAT3 | c.6020T>A p.V2007D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV53073679, COSV53109706; called by muse, mutect2, varscan2
- FAT3 | c.8771T>G p.F2924C | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53109731; called by muse, mutect2, varscan2
- FAT4 | c.9695C>T p.A3232V | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs373873722; called by muse, mutect2, varscan2
- FBLN7 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs761948832, COSV58666173; called by mutect2, varscan2
- FBXL2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV52138732; called by muse, mutect2, varscan2
- FES | c.1328C>A p.P443Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV60998304; called by muse, mutect2, varscan2
- FFAR2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.313); catalogued as rs775045094, COSV55832218; called by muse, mutect2, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 44/197 reads (22%) | catalogued as rs749851531; called by mutect2, pindel, varscan2
- FILIP1 | c.2854A>G p.I952V | Missense Mutation (SNP) | VAF 53/240 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV52729574; called by muse, mutect2, varscan2
- FKBPL | c.845A>G p.E282G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV100913524; called by muse, mutect2, varscan2
- FN1 | c.4654G>A p.D1552N | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs140153061, COSV60547202; called by muse, mutect2, varscan2
- FOXA1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs754657304, COSV51645819; called by muse, mutect2, varscan2
- FOXC2 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1357660848, COSV100234036; called by muse, mutect2, varscan2
- FOXG1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57396772; called by muse, varscan2
- FOXJ1 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs748812424, COSV53944137; called by muse, mutect2, varscan2
- FOXP3 | c.128del p.G43Efs*19 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs1557116712; called by mutect2, pindel, varscan2
- FPGT-TNNI3K | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63043842; called by muse, mutect2, varscan2
- FRA10AC1 | c.621del p.K207Nfs*2 | Frame Shift Del (DEL) | VAF 29/114 reads (25%) | catalogued as rs750462341; called by mutect2, pindel, varscan2
- FRMPD2 | c.2177G>A p.G726D | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59717947; called by muse, mutect2, varscan2
- FURIN | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as rs770393100, COSV51576729; called by muse, mutect2, varscan2
- FUT2 | c.646del p.V216Wfs*71 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | catalogued as COSV101218174; called by mutect2, pindel, varscan2
- FUT6 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs112849079, COSV54605837; called by muse, mutect2, varscan2
- FZD1 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368484423, COSV55310440; called by muse, mutect2, varscan2
- GABBR2 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52303572; called by muse, mutect2, varscan2
- GABBR2 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV52303583; called by muse, mutect2, varscan2
- GABRA5 | c.719G>T p.S240I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.457); catalogued as COSV100164614; called by muse, varscan2
- GABRG1 | c.784del p.I262Ffs*5 | Frame Shift Del (DEL) | VAF 44/251 reads (18%) | catalogued as COSV54957450; called by mutect2, pindel, varscan2
- GALNT15 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007560281, COSV60216095; called by muse, mutect2, varscan2
- GALNT16 | c.956del p.G319Efs*83 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs763094427; called by mutect2, pindel, varscan2
- GASK1B | c.1268G>T p.R423M | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56707303; called by muse, mutect2, varscan2
- GATAD2A | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs370240766; called by muse, mutect2, varscan2
- GBP4 | c.1859T>C p.V620A | Missense Mutation (SNP) | VAF 93/304 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs61746918, COSV63254284; called by muse, mutect2, varscan2
- GBP5 | c.868+1G>A p.X290_splice | Splice Site (SNP) | VAF 41/189 reads (22%) | catalogued as rs140405391; called by muse, mutect2, varscan2
- GCC1 | c.1924G>T p.A642S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.787); catalogued as COSV58462604; called by muse, mutect2, varscan2
- GGA2 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs760553146, COSV59168565; called by muse, mutect2, varscan2
- GIGYF2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 17/117 reads (15%) | catalogued as COSV65254768; called by muse, mutect2, varscan2
- GLB1L2 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV60278590; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 30/146 reads (21%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GMDS | c.445A>T p.K149* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV66434282; called by muse, mutect2, varscan2
- GNA12 | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV51740924; called by muse, mutect2, varscan2
- GNAS | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV58335091; called by muse, mutect2, varscan2
- GON4L | c.5326C>A p.H1776N | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV55193425; called by muse, mutect2, varscan2
- GORASP1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as rs1053094276, COSV56529948; called by muse, mutect2, varscan2
- GP9 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV100264561; called by muse, mutect2
- GPAA1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782263637, COSV60155635, COSV60155723; called by muse, mutect2, varscan2
- GPATCH8 | c.3491C>A p.S1164Y | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59194899; called by muse, mutect2, varscan2
- GPHA2 | c.103+1G>A p.X35_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as rs528889811, COSV51210288; called by muse, mutect2, varscan2
- GPR161 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as rs761465932, COSV54790211; called by muse, varscan2
- GPR180 | c.173T>A p.I58N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100978980; called by muse, mutect2, varscan2
- GPT | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs777867324, COSV52953103; called by muse, mutect2, varscan2
- GREB1 | c.4265C>T p.A1422V | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.341); catalogued as rs1469707242, COSV99301970; called by muse, mutect2, varscan2
- GRK7 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs377464259, COSV53822939; called by muse, mutect2, varscan2
- GRM2 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as rs764682062, COSV56584872; called by muse, mutect2, varscan2
- GRM3 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV64471627; called by muse, mutect2, varscan2
- GRM6 | c.1676C>A p.P559H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV99179410; called by muse, mutect2
- GRM6 | c.727dup p.V243Gfs*40 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | catalogued as rs281865186; ClinVar: not provided; called by mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs754199513; called by mutect2, varscan2
- GSE1 | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as rs1290372124, COSV53672044; called by muse, mutect2, varscan2
- GSPT1 | c.360T>A p.T120= (on ENST00000420576 / NM_001130007.2; = p.T258= on NM_002094.4) | Splice Region (SNP) | VAF 49/182 reads (27%) | catalogued as COSV101341680; called by muse, mutect2, varscan2
- GZMA | c.86T>A p.I29N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57113137, COSV99956449; called by muse, mutect2, varscan2
- H1-2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs561654336, COSV100642205, COSV100642321; called by muse, mutect2, varscan2
- H2BC13 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.055); catalogued as COSV62440770; called by muse, mutect2, varscan2
- H2BC14 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as COSV60797686; called by muse, mutect2, varscan2
- HEATR4 | c.2332A>G p.K778E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV58572670; called by muse, mutect2, varscan2
- HEXIM2 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56236414; called by muse, mutect2, varscan2
- HNRNPAB | c.391_393del p.K131del | In Frame Del (DEL) | VAF 27/87 reads (31%) | catalogued as rs1369492425; called by mutect2, pindel, varscan2
- HOXA3 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.755); catalogued as COSV57826389; called by muse, mutect2, varscan2
- HOXD9 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV50891647; called by mutect2, varscan2
- HS3ST5 | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.775); catalogued as COSV57140397; called by muse, mutect2, varscan2
- HSD17B14 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as rs755171561, COSV54412491; called by muse, mutect2, varscan2
- HSPB8 | c.219del p.T74Lfs*27 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as COSV56137562; called by mutect2, pindel, varscan2
- HTR2A | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66327301; called by muse, mutect2, varscan2
- HTR3A | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55469465; called by muse, mutect2, varscan2
- HYAL2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs782059591, COSV51700596; called by muse, mutect2, varscan2
- HYOU1 | c.884G>T p.R295I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as COSV68215803; called by muse, mutect2, varscan2
- IFI27L2 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs774005783, COSV53128212; called by muse, mutect2, varscan2
- IFT172 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs148237432; called by muse, mutect2, varscan2
- IFT43 | c.147G>A p.E49= | Splice Region (SNP) | VAF 16/60 reads (27%) | catalogued as rs749711311, COSV53138647; called by muse, mutect2, varscan2
- IFT57 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 30/194 reads (15%) | catalogued as rs1017459667, COSV52708830; called by muse, mutect2, varscan2
- IFT74 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101197112; called by muse, mutect2, varscan2
- IGF2BP1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs777305494, COSV51731272; called by muse, mutect2, varscan2
- IGFALS | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV51905807; called by muse, mutect2, varscan2
- IGHD | c.1028C>A p.P343Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as COSV101162776; called by muse, mutect2, varscan2
- IGSF3 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs146751671; called by muse, mutect2, varscan2
- IL12RB2 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV52023272; called by muse, mutect2, varscan2
- IL17RD | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV56337945; called by muse, mutect2, varscan2
- IL20RA | c.514A>G p.M172V | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100359799, COSV57358325; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 56/107 reads (52%) | catalogued as rs745545309; called by mutect2, pindel, varscan2
- ING2 | c.521A>G p.D174G | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs770426903, COSV56564218; called by muse, mutect2, varscan2
- INPP5F | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs1460251213, COSV62820369; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs373727561; called by muse, mutect2, varscan2
- IQCE | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867032551, COSV58077124; called by muse, mutect2
- IQGAP2 | c.359T>C p.M120T | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57173386; called by muse, mutect2, varscan2
- IRGQ | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60670710; called by muse, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- ITGA3 | c.3019G>T p.G1007W | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50311565; called by muse, mutect2, varscan2
- ITGA5 | c.2056G>A p.G686S | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99516107; called by muse, mutect2, varscan2
- ITGA9 | c.1327+2T>C p.X443_splice | Splice Site (SNP) | VAF 40/146 reads (27%) | catalogued as rs367550460; called by muse, mutect2, varscan2
- ITGAX | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs200320931, COSV51643641; called by mutect2, varscan2
- ITGB4 | c.2756G>A p.G919D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52325856; called by muse, mutect2, varscan2
- ITIH3 | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69648869; called by muse, mutect2, varscan2
- JAG2 | c.2915G>A p.R972H | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs372934981; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as rs755650243; called by mutect2, varscan2
- JMJD4 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV59917913; called by muse, mutect2, varscan2
- JRK | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs782712137, COSV70629847; called by muse, mutect2, varscan2
- JUNB | c.377del p.G126Afs*24 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs1425641451; called by mutect2, pindel, varscan2
- KALRN | c.6737G>T p.R2246M (on ENST00000360013 / NM_001024660.4; = p.R549M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV52256255; called by muse, mutect2, varscan2
- KANK1 | c.3616G>A p.A1206T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779819624, COSV66527976; called by muse, mutect2, varscan2
- KCNA6 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.963); catalogued as COSV54975224; called by muse, mutect2, varscan2
- KCND3 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs1483590521, COSV56174041; called by muse, mutect2, varscan2
- KCNG1 | c.1247G>T p.W416L | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100856996, COSV65369084; called by muse, mutect2, varscan2
- KCNMB3 | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV58570536, COSV58571844; called by muse, mutect2, varscan2
- KCNN3 | c.2078C>T p.A693V (on ENST00000618040 / NM_001204087.1; = p.A678V on NM_002249.6) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs371429880; called by muse, mutect2, varscan2
- KCNS1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60260131; called by muse, mutect2, varscan2
- KCNV1 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV52086104, COSV99818838; called by muse, mutect2, varscan2
- KDM1A | c.1028C>A p.A343D | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV63088066; called by muse, mutect2, varscan2
- KDM1B | c.2158G>A p.A720T (on ENST00000449850; = p.A487T on NM_153042.4) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs752633222, COSV52808727; called by mutect2, varscan2
- KHDRBS1 | c.934del p.A312Lfs*8 | Frame Shift Del (DEL) | VAF 22/104 reads (21%) | catalogued as COSV56982946; called by mutect2, pindel, varscan2
- KHSRP | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101231116; called by muse, mutect2, varscan2
- KIAA1522 | c.2995A>G p.T999A (on ENST00000373480 / NM_001198972.2; = p.T1058A on NM_020888.3) | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53864521; called by muse, mutect2, varscan2
- KIF1B | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55808654; called by muse, mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF26B | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV68572388; called by muse, mutect2
- KIF3A | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV66414514; called by muse, mutect2, varscan2
- KIRREL1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs866838069; called by muse, mutect2
- KLHL32 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs150244885; called by muse, mutect2, varscan2
- KLHL36 | c.1352dup p.H452Pfs*42 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | catalogued as rs746466551; called by mutect2, pindel, varscan2
- KLHL41 | c.1416dup p.G473Rfs*22 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | catalogued as rs749464576; called by mutect2, pindel, varscan2
- KMT2D | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); catalogued as rs371225040; called by muse, mutect2, varscan2
- KPNA3 | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as COSV55504513; called by muse, mutect2, varscan2
- KRT6C | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 122/319 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs187821450, COSV52877728; called by muse, mutect2, varscan2
- KRT84 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs539883178, COSV99230689; called by muse, mutect2, varscan2
- L34079.1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1392318784, COSV60670890; called by muse, varscan2
- LAMB3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs761752478, COSV61916869; called by muse, mutect2, varscan2
- LAMB4 | c.4289G>A p.R1430H | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1293472494, COSV52732914; called by muse, mutect2
- LARP1 | c.434del p.P145Qfs*10 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as COSV60428595; called by mutect2, pindel, varscan2
- LAS1L | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.725); catalogued as COSV56707326; called by muse, mutect2, varscan2
- LEPR | c.3268_3269dup p.S1090Rfs*6 | Frame Shift Ins (INS) | VAF 36/110 reads (33%) | catalogued as rs1553174844; called by mutect2, varscan2
- LEXM | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs777462327, COSV64022668; called by muse, mutect2, varscan2
- LGR6 | c.1775del p.V592Afs*10 (on ENST00000367278 / NM_001017403.1; = p.V540Afs*10 on NM_021636.3) | Frame Shift Del (DEL) | VAF 23/107 reads (21%) | catalogued as rs113146160, COSV55152990; called by mutect2, pindel, varscan2
- LHX9 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs577856015, COSV61328690; called by muse, mutect2, varscan2
- LIPE | c.2284G>A p.A762T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs746826569, COSV54926692; called by muse, mutect2, varscan2
- LMAN1L | c.1417C>T p.Q473* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV59001972, COSV59002536; called by muse, mutect2, varscan2
- LPA | c.2837A>G p.Q946R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100305770, COSV60301253; called by muse, mutect2
- LRIG3 | c.2988G>T p.K996N | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.074); catalogued as COSV57863657; called by muse, mutect2, varscan2
- LRRC52 | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV99673603; called by muse, mutect2, varscan2
- LRRK2 | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.61); catalogued as rs777298637, COSV54153167; called by muse, mutect2, varscan2
- LSR | c.403C>A p.R135S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61555997; called by muse, mutect2, varscan2
- LSR | c.886C>A p.P296T (on ENST00000361790; = p.P277T on NM_015925.6) | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV61555089; called by muse, mutect2, varscan2
- LYPD3 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.579); catalogued as COSV54988369; called by muse, varscan2
- LZTFL1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs759640480, COSV56111441; called by muse, mutect2, varscan2
- LZTS3 | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100232074; called by muse, mutect2, varscan2
- MAGEB16 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.133); catalogued as COSV67873928; called by muse, mutect2, varscan2
- MAGEB2 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV66780729; called by muse, mutect2, varscan2
- MAGEB4 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs761685473, COSV66775735; called by muse, mutect2, varscan2
- MANEA | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV62589657; called by muse, mutect2, varscan2
- MAPKAPK5 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV72431623; called by muse, mutect2, varscan2
- MASP1 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51459842; called by muse, mutect2, varscan2
- MAST3 | c.1755del p.E586Rfs*49 | Frame Shift Del (DEL) | VAF 75/334 reads (22%) | catalogued as rs1568591333; called by mutect2, pindel, varscan2
- MDN1 | c.3164C>T p.T1055M | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs745553494, COSV65525330; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs762115034; called by mutect2, varscan2
- MEMO1 | c.212+1G>A p.X71_splice | Splice Site (SNP) | VAF 92/354 reads (26%) | catalogued as rs948942270, COSV54452083; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs745891632; called by mutect2, varscan2
- METTL23 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100333336; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs765803753; called by mutect2, pindel
- MIGA2 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs202169772; called by muse, mutect2, varscan2
- MINDY4 | c.1688G>A p.G563D | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs561526056, COSV54673638; called by muse, mutect2, varscan2
- MINK1 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 33/115 reads (29%) | catalogued as COSV61794472; called by muse, mutect2, varscan2
- MINK1 | c.3397G>A p.A1133T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1042289018, COSV53416570; called by muse, mutect2, varscan2
- MKNK1 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57861263; called by muse, mutect2, varscan2
- MMP12 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs202044860, COSV100404773; called by muse, mutect2, varscan2
- MMP14 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs758484236, COSV61288228; called by muse, mutect2, varscan2
- MMP15 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54679791; called by muse, mutect2, varscan2
- MNT | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.074); catalogued as rs750625027, COSV51511008; called by mutect2, varscan2
- MORC1 | c.2800-1G>T p.X934_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | catalogued as COSV51719869; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 14/80 reads (18%) | catalogued as rs777649506, COSV53202254; called by pindel, varscan2
- MOSPD3 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56158210; called by muse, mutect2, varscan2
- MPPED2 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100813057; called by muse, mutect2, varscan2
- MRGPRE | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs766954894, COSV101099950; called by mutect2, varscan2
- MRPL13 | c.152-1G>C p.X51_splice | Splice Site (SNP) | VAF 19/109 reads (17%) | catalogued as COSV60367499; called by muse, mutect2
- MS4A14 | c.1121A>G p.D374G | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55734876; called by muse, mutect2, varscan2
- MTNR1B | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.299); catalogued as rs549634756, COSV57066014; called by muse, mutect2, varscan2
- MUC16 | c.34178C>T p.T11393I | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.475); catalogued as COSV67465606; called by muse, mutect2, varscan2
- MYB | c.1430A>G p.Q477R | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57198191; called by muse, mutect2, varscan2
- MYCN | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs144939456, COSV55258707; called by muse, mutect2, varscan2
- MYEOV | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV100456549; called by muse, mutect2, varscan2
- MYH11 | c.5692G>A p.A1898T | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.941); catalogued as rs1363749589, COSV55553063; called by muse, mutect2, varscan2
- MYH2 | c.2053A>G p.K685E | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99818975; called by muse, varscan2
- MYH6 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs746646172, CM1110149, COSV62449720, COSV62450610; called by mutect2, varscan2
- MYH8 | c.4234G>A p.A1412T | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs200412862, COSV67964989; called by muse, mutect2, varscan2
- MYL5 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100424583, COSV100424715; called by muse, mutect2, varscan2
- MYO6 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs760672339, COSV64117739; called by muse, mutect2, varscan2
- MYO7B | c.1604A>G p.N535S | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.214); catalogued as COSV67347683; called by muse, mutect2, varscan2
- MYO9B | c.4861C>T p.R1621W | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs373284114; ClinVar: uncertain significance; called by mutect2, varscan2
- MYO9B | c.5551G>A p.A1851T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759537296, COSV68277351; called by muse, mutect2, varscan2
- MYOC | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV50674831; called by muse, mutect2, varscan2
- N4BP2 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as COSV54701868; called by muse, mutect2, varscan2
- NAV3 | c.4105C>A p.L1369I | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57074109, COSV57079560; called by muse, mutect2, varscan2
- NCBP1 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64316737; called by muse, mutect2, varscan2
- NCOA5 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs776509008, COSV51644097, COSV51644156; called by muse, mutect2, varscan2
- NEB | c.7343G>A p.R2448H | Missense Mutation (SNP) | VAF 101/337 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373589529, COSV51135223; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NEK3 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs756770781, COSV51616877; called by muse, mutect2, varscan2
- NFE2L1 | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100671291; called by muse, mutect2, varscan2
- NGDN | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.243); catalogued as COSV68142399; called by muse, mutect2, varscan2
- NHS | c.567C>A p.P189= | Splice Region (SNP) | VAF 41/74 reads (55%) | catalogued as COSV101196321, COSV66280184; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as rs145147241; called by mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs763440516; called by mutect2, varscan2
- NLRC3 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.322); catalogued as COSV100072270; called by muse, mutect2, varscan2
- NOMO2 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 114/1345 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as rs1335507015, COSV100395465; called by muse, varscan2
- NRDC | c.1495+2T>G p.X499_splice | Splice Site (SNP) | VAF 19/108 reads (18%) | catalogued as COSV61404300; called by muse, mutect2, varscan2
- NRN1 | c.100G>T p.V34F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55205584, COSV55206198; called by muse, varscan2
- NRXN1 | c.2392C>A p.L798I | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV58452321, COSV58462624; called by muse, mutect2, varscan2
- NRXN2 | c.808del p.A270Pfs*57 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs754860965; called by mutect2, varscan2
- NTM | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs202188991, COSV66179918; called by muse, mutect2, varscan2
- NUTM1 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV60995348; called by muse, mutect2, varscan2
- NXPE1 | c.793G>A p.V265I (on ENST00000424269; = p.V123I on NM_152315.5) | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99319749; called by muse, mutect2, varscan2
- NYAP1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776432115, COSV55718814; called by muse, mutect2, varscan2
- NYAP2 | c.945dup p.K316Qfs*116 | Frame Shift Ins (INS) | VAF 26/106 reads (25%) | catalogued as rs758750309; called by mutect2, varscan2
- NYNRIN | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as rs201881306, COSV66842428; called by muse, mutect2
- OBSCN | c.17710G>A p.V5904M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs781324389, COSV52773803; called by muse, mutect2, varscan2
- ODF3 | c.676-2A>G p.X226_splice | Splice Site (SNP) | VAF 29/73 reads (40%) | catalogued as COSV57293779; called by muse, mutect2, varscan2
- OGDHL | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs760518509, COSV65102202; called by muse, mutect2, varscan2
- OPA1 | c.1504A>G p.I502V (on ENST00000361510 / NM_130837.3; = p.I447V on NM_015560.3) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.309); catalogued as COSV62480607; called by muse, mutect2, varscan2
- OPN3 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs770842729, COSV59364204, COSV59364701; called by muse, mutect2, varscan2
- OR10Z1 | c.265dup p.D89Gfs*23 | Frame Shift Ins (INS) | VAF 42/161 reads (26%) | catalogued as rs752054889; called by mutect2, varscan2
- OR2L3 | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 64/296 reads (22%) | catalogued as COSV63454887; called by muse, varscan2
- OR51B2 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV60916635; called by muse, mutect2, varscan2
- OR52E2 | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as COSV58612572; called by muse, mutect2, varscan2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 42/211 reads (20%) | catalogued as rs1031417078; called by mutect2, varscan2
- OR8B2 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.138); catalogued as COSV66664656; called by muse, mutect2, varscan2
- ORM2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 94/582 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs768724177, COSV99407383; called by muse, mutect2, varscan2
- OTOA | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.797); catalogued as COSV53754367; called by muse, mutect2, varscan2
- OTUD7A | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61038840; called by muse, mutect2, varscan2
- PACC1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs747223607, COSV54787893; called by muse, mutect2, varscan2
- PAK4 | c.565del p.Q189Sfs*180 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs1217359611; called by mutect2, pindel, varscan2
- PALLD | c.3338C>T p.T1113I (on ENST00000505667 / NM_001166108.2; = p.T1096I on NM_016081.4) | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99823557; called by muse, mutect2, varscan2
- PAMR1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as rs757758192, COSV53512436; called by muse, mutect2, varscan2
- PAMR1 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs201076075, COSV53512453; called by muse, mutect2, varscan2
- PARP1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.545); catalogued as rs202057244, COSV64687881; called by muse, mutect2, varscan2
- PATJ | c.2171T>C p.V724A | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV100332796; called by muse, varscan2
- PAXIP1 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs768008816, COSV68185182; called by muse, mutect2, varscan2
- PCDHA7 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs782034445, COSV65342515; called by muse, mutect2, varscan2
- PCDHB15 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1281245820, COSV99178797; called by muse, mutect2, varscan2
- PCDHB8 | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as rs781878337, COSV50767740; called by muse, mutect2, varscan2
- PCDHGA12 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.166); catalogued as COSV52743421; called by muse, mutect2, varscan2
- PCF11 | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53531136; called by muse, varscan2
- PCNT | c.6767C>T p.A2256V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs750262978, COSV64028176; called by muse, mutect2, varscan2
- PDE8B | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763895280, COSV53735448; called by muse, mutect2, varscan2
- PDPR | c.1688C>A p.T563N | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99847569; called by muse, mutect2, varscan2
- PDS5A | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as COSV57825783; called by muse, mutect2, varscan2
- PDZD2 | c.1713G>T p.Q571H | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV56858284; called by muse, mutect2, varscan2
- PDZD2 | c.2113G>T p.G705C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56858290; called by muse, mutect2, varscan2
- PDZD7 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148695069, CM1513240, COSV64646209; called by muse, mutect2, varscan2
- PDZRN4 | c.1924G>T p.E642* (on ENST00000402685 / NM_001164595.2; = p.E384* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV54201500; called by muse, mutect2, varscan2
- PEG3 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs762141634, COSV55631527, COSV55638935; called by muse, mutect2, varscan2
- PER2 | c.2327C>A p.P776H | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as rs1402981312, COSV54523667, COSV54523867; called by muse, mutect2, varscan2
- PGM3 | c.591+1G>A p.X197_splice | Splice Site (SNP) | VAF 20/76 reads (26%) | catalogued as rs1299450046, COSV52283868; called by muse, mutect2, varscan2
- PHAX | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs778195369, COSV52551190; called by muse, mutect2, varscan2
- PHF14 | c.946del p.M316Wfs*5 | Frame Shift Del (DEL) | VAF 40/194 reads (21%) | catalogued as COSV68854594; called by mutect2, pindel, varscan2
- PHF14 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 34/166 reads (20%) | catalogued as rs968269919, COSV68855345; called by muse, varscan2
- PHF2 | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100822949; called by muse, varscan2
- PHF24 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs776629054, COSV54274380; called by muse, mutect2, varscan2
- PHKA2 | c.3610G>A p.A1204T | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748453047, COSV101177084, COSV66053923; called by muse, mutect2, varscan2
- PI4KA | c.4945G>A p.A1649T | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs760693636, COSV99743658; called by muse, mutect2, varscan2
- PIGT | c.1730del p.P577Hfs*67 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs760395465; called by mutect2, pindel, varscan2
- PIK3C2A | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV56402813; called by muse, mutect2, varscan2
- PIK3R4 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs770589427, COSV63244090; called by muse, mutect2, varscan2
- PINX1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs372632631; called by muse, mutect2, varscan2
- PITPNM3 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs536434931, COSV52595536; called by muse, mutect2, varscan2
- PIWIL3 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV59995419; called by muse, mutect2, varscan2
- PLEKHG5 | c.483G>T p.Q161H (on ENST00000400915 / NM_001042663.3; = p.Q124H on NM_020631.6) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61702031; called by muse, mutect2, varscan2
- PLIN4 | c.3139G>A p.A1047T (on ENST00000301286; = p.A1062T on NM_001367868.2) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs781509044, COSV56691134; called by muse, mutect2
- PLXNA2 | c.3718G>A p.V1240I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as rs746253674, COSV65440681; called by muse, mutect2, varscan2
- PNMA8B | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66536549; called by muse, mutect2, varscan2
- PNPLA5 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.122); catalogued as COSV53374799; called by muse, mutect2, varscan2
- POLD1 | c.2555T>G p.L852R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1351034464, COSV54530607; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLI | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.496); catalogued as rs969095032, COSV54189210, COSV54190031; called by muse, mutect2, varscan2
- POLR1B | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54498053; called by muse, mutect2, varscan2
- POLR2A | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59492226; called by muse, mutect2, varscan2
- POLRMT | c.3658G>A p.E1220K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1438633183, COSV52114647; called by muse, mutect2, varscan2
- POTEF | c.617del p.K206Rfs*5 | Frame Shift Del (DEL) | VAF 64/327 reads (20%) | catalogued as COSV62544958; called by mutect2, pindel, varscan2
- PPFIBP2 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 69/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs769820633, COSV55074475; called by muse, mutect2, varscan2
- PPHLN1 | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV56731213; called by muse, mutect2, varscan2
- PPP1R12A | c.1061G>T p.S354I | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54108267; called by muse, mutect2, varscan2
- PPP1R3F | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs199740337, COSV50018398; called by muse, mutect2, varscan2
- PPP1R42 | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as rs774838939, COSV61207641; called by muse, mutect2, varscan2
- PPP6R2 | c.2561del p.P854Rfs*23 (on ENST00000216061 / NM_001365836.1; = p.P820Rfs*23 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV53291064; called by mutect2, pindel, varscan2
- PPTC7 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as rs756525742, COSV62826161; called by muse, mutect2, varscan2
- PRKCI | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99855570; called by muse, mutect2, varscan2
- PRKD3 | c.2540G>A p.R847H | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1405945703, COSV50017506; called by muse, mutect2, varscan2
- PRRC2A | c.3164G>A p.R1055H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs747263936, COSV65685049; called by mutect2, varscan2
- PRTG | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66836796, COSV66837991; called by muse, mutect2, varscan2
- PTCH1 | c.3740C>T p.A1247V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV59474076; called by muse, mutect2, varscan2
- PTP4A3 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1241185896, COSV61470989; called by muse, mutect2, varscan2
- PTPRK | c.4121T>A p.I1374N (on ENST00000368215 / NM_001291984.2; = p.I1375N on NM_002844.4) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV63897760; called by muse, mutect2, varscan2
- PTPRO | c.2390G>A p.S797N | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55510497; called by muse, mutect2, varscan2
- PXDC1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs774517433, COSV66661532; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs144926498, COSV57928978; called by muse, mutect2, varscan2
- RABL6 | c.1557del p.W520Gfs*79 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs755631481, COSV100272944; called by mutect2, varscan2
- RADX | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV65318603; called by muse, mutect2
- RALGAPB | c.2465C>G p.A822G | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99484515; called by muse, mutect2, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 47/170 reads (28%) | catalogued as rs770990761; called by mutect2, varscan2
- RARA | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.527); catalogued as rs754292583, COSV54192246; called by muse, mutect2, varscan2
- RBM10 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV99333212; called by muse, mutect2, varscan2
- RBM14 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV59557741; called by muse, mutect2, varscan2
- RBM43 | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV58878740; called by muse, mutect2, varscan2
- RBP3 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555211350; called by muse, mutect2, varscan2
- RECQL5 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58640319; called by muse, mutect2, varscan2
- RELN | c.3874G>A p.D1292N | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV59002045; called by muse, mutect2, varscan2
- REV3L | c.5654dup p.S1886Kfs*2 | Frame Shift Ins (INS) | VAF 18/108 reads (17%) | catalogued as rs761303551; called by mutect2, varscan2
- RFX7 | c.3832A>G p.N1278D (on ENST00000559447 / NM_001368074.1; = p.N1375D on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV57963338; called by muse, mutect2, varscan2
- RHBDF2 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs376555925, COSV57423201; called by muse, mutect2, varscan2
- RHOF | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746745426, COSV57363206; called by muse, mutect2, varscan2
- RIMKLB | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV55236273; called by muse, varscan2
- RIMS1 | c.54del p.M19Cfs*7 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs1378143186; called by mutect2, pindel, varscan2
- RIN1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.871); catalogued as rs779921706, COSV60926495; called by muse, mutect2, varscan2
- RING1 | c.1090T>C p.Y364H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100761697; called by muse, mutect2
- RNF213 | c.11906G>T p.G3969V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV60397394; called by muse, mutect2, varscan2
- RNF213 | c.14282G>A p.G4761D | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV60397412; called by muse, mutect2
- RNF6 | c.1778dup p.L593Ffs*4 | Frame Shift Ins (INS) | VAF 34/150 reads (23%) | catalogued as rs1199638878; called by mutect2, varscan2
- ROBO4 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.369); catalogued as COSV100127173, COSV60627644; called by muse, mutect2, varscan2
- ROCK1 | c.3242C>A p.A1081D | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67696016; called by muse, mutect2, varscan2
- ROR2 | c.1770del p.D591Tfs*32 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as COSV65217415; called by mutect2, pindel
- RPRD2 | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV64820212; called by muse, mutect2, varscan2
- RPS6KL1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746273906, COSV100665151, COSV63581148; called by muse, mutect2, varscan2
- RPUSD2 | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs532193389, COSV59765499; called by muse, mutect2, varscan2
- RRP8 | c.648dup p.T217Hfs*16 | Frame Shift Ins (INS) | VAF 28/111 reads (25%) | catalogued as rs1216641054; called by mutect2, pindel, varscan2
- RSRC2 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.549); catalogued as rs1483084057, COSV59204431; called by muse, mutect2, varscan2
- RUNDC3A | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.417); catalogued as rs1249914630, COSV56587459; called by muse, mutect2, varscan2
- RUVBL2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs761782658, COSV55485205; called by muse, mutect2, varscan2
- RUVBL2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV55485217; called by muse, mutect2, varscan2
- SALL4 | c.3147G>T p.K1049N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53852198; called by muse, mutect2, varscan2
- SAMD11 | c.1936T>C p.S646P | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV58986994; called by muse, mutect2, varscan2
- SASH1 | c.2736G>T p.E912D | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs746649534, COSV66561665; called by muse, mutect2, varscan2
- SCARA5 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412660652, COSV61572048; called by muse, mutect2, varscan2
- SCGB1D4 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); catalogued as COSV62203988; called by muse, mutect2, varscan2
- SCN4A | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV71126867; called by muse, mutect2, varscan2
- SCRN3 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV55807583; called by muse, mutect2, varscan2
- SDCCAG8 | c.842G>C p.G281A | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV59409243; called by muse, mutect2, varscan2
- SDCCAG8 | c.1970A>G p.E657G | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59409258; called by muse, mutect2, varscan2
- SDHB | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV64965232; called by muse, mutect2, varscan2
- SEMA6A | c.2637dup p.K880Qfs*36 | Frame Shift Ins (INS) | VAF 40/159 reads (25%) | catalogued as rs749631581; called by mutect2, pindel, varscan2
- SEMA7A | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371438755; called by muse, mutect2, varscan2
- SERPINI2 | c.300dup p.Q101Tfs*6 | Frame Shift Ins (INS) | VAF 9/81 reads (11%) | catalogued as rs780651251; called by mutect2, pindel, varscan2
- SETD7 | c.1026del p.K344Rfs*14 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs35259575; called by mutect2, pindel, varscan2
- SGPP2 | c.427del p.R143Vfs*8 | Frame Shift Del (DEL) | VAF 12/128 reads (9%) | catalogued as COSV58331223; called by mutect2, pindel
- SH3GL3 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1452155988, COSV61056722; called by muse, mutect2, varscan2
- SHANK2 | c.2923G>T p.A975S | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.423); catalogued as COSV53598006; called by muse, mutect2, varscan2
- SHLD1 | c.303A>T p.R101S | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.294); catalogued as COSV57436608; called by muse, mutect2
- SHPRH | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1440604738, COSV51609838; called by muse, mutect2, varscan2
- SHROOM1 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV60581310; called by muse, mutect2, varscan2
- SIPA1L2 | c.2539G>A p.A847T | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1435945095, COSV53390384; called by muse, mutect2, varscan2
- SIPA1L3 | c.2337del p.I780Sfs*21 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs748827733, COSV55912723; called by mutect2, pindel, varscan2
- SIRPD | c.592T>C p.*198Qext*42 | Nonstop Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as COSV67546618; called by muse, mutect2, varscan2
- SIX4 | c.1394A>G p.D465G | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV53669557; called by muse, mutect2, varscan2
- SLC10A5 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as rs778372054, COSV72828204, COSV72828340; called by muse, mutect2, varscan2
- SLC22A9 | c.1497G>T p.W499C | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374697464, COSV54167180; called by muse, mutect2, varscan2
- SLC25A13 | c.405A>C p.Q135H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs768953296, COSV55704372, COSV99672874; called by muse, mutect2, varscan2
- SLC25A16 | c.144C>A p.C48* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV56264957, COSV56266303; called by muse, mutect2
- SLC34A3 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1357607083, COSV63187050; called by muse, mutect2, varscan2
- SLC35B3 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100217097; called by muse, mutect2, varscan2
- SLC38A6 | c.943T>A p.L315I | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV50782378; called by muse, mutect2, varscan2
- SLC39A10 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62767397; called by muse, mutect2, varscan2
- SLC39A13 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs369854018; called by muse, mutect2, varscan2
- SLC39A3 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs770897898, COSV99514035; called by muse, mutect2
- SLC39A6 | c.839T>G p.V280G | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV99309250; called by muse, mutect2, varscan2
- SLC47A2 | c.1124T>C p.I375T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100327761; called by mutect2, varscan2
- SLC4A8 | c.2683A>G p.M895V | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV100176295; called by muse, mutect2, varscan2
- SLC52A1 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.985); catalogued as COSV54692935; called by muse, mutect2, varscan2
- SLC52A2 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57351868; called by muse, mutect2, varscan2
- SLC5A4 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751394836, COSV56669070; called by muse, mutect2, varscan2
- SLC5A6 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as rs546600819, COSV60159005; called by muse, mutect2, varscan2
- SLC9A1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as rs755250713, COSV56053366; called by muse, mutect2, varscan2
- SLITRK1 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); catalogued as rs1233205975, COSV100999721; called by muse, mutect2, varscan2
- SLTM | c.1460del p.N487Ifs*35 | Frame Shift Del (DEL) | VAF 48/194 reads (25%) | catalogued as rs762322084; called by mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | catalogued as rs747405143; called by mutect2, pindel, varscan2
- SMURF2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as COSV52315361; called by muse, mutect2, varscan2
- SMYD1 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV70225152; called by muse, mutect2, varscan2
- SNED1 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.503); catalogued as rs750619657, COSV60024192; called by muse, mutect2, varscan2
- SNX31 | c.308A>T p.K103I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV61263042; called by muse, mutect2, varscan2
- SOGA1 | c.2168A>T p.E723V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52918486; called by muse, mutect2, varscan2
- SORCS1 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs772470615, COSV53866301, COSV99548752; called by muse, mutect2, varscan2
- SPHKAP | c.929G>T p.R310I | Missense Mutation (SNP) | VAF 140/521 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60874187; called by muse, mutect2, varscan2
- SPRYD3 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV56853789; called by muse, mutect2, varscan2
- SPTA1 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.826); catalogued as rs769044905, COSV63753000; called by muse, mutect2, varscan2
- SPTB | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as rs942424375, COSV67631796; called by muse, mutect2, varscan2
- SPTLC1 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as COSV52764095; called by muse, mutect2, varscan2
- SPTSSA | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.956); catalogued as COSV53294674; called by muse, mutect2, varscan2
- SQLE | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs1187664306, COSV56280745; called by muse, mutect2, varscan2
- STAT5A | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.582); catalogued as rs1220900989, COSV61806682; called by muse, mutect2, varscan2
- STAU1 | c.631C>T p.P211S (on ENST00000371856 / NM_001319135.1; = p.P130S on NM_004602.3) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61460268; called by muse, mutect2, varscan2
- STK11IP | c.3262C>T p.R1088* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as rs202148315; called by muse, mutect2, varscan2
- STOX1 | c.2836G>A p.G946R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV53814913; called by muse, mutect2, varscan2
- STT3A | c.905T>A p.V302D | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV67064736; called by muse, mutect2, varscan2
- SULF1 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV52681248; called by muse, mutect2, varscan2
- SULT1E1 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99894577; called by muse, mutect2, varscan2
- SUN1 | c.1411C>T p.R471C (on ENST00000405266 / NM_001367651.1; = p.R351C on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193306641, COSV61779237; called by muse, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYNE1 | c.24604C>T p.R8202C (on ENST00000367255 / NM_182961.4; = p.R8131C on NM_033071.3) | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280986749, COSV99549489; called by muse, mutect2, varscan2
- SYNE2 | c.3359A>T p.D1120V | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100646354; called by muse, mutect2, varscan2
- SYT12 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs753483556, COSV101210785; called by muse, mutect2, varscan2
- SYT17 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV62546130; called by muse, mutect2, varscan2
- SZT2 | c.8629C>T p.R2877C (on ENST00000634258 / NM_001365999.1; = p.R2820C on NM_015284.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs543404828, COSV65169822; called by muse, mutect2, varscan2
- TAGAP | c.1856C>T p.T619M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs773179199, COSV57851186, COSV57851482; called by muse, mutect2, varscan2
- TAGLN | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs780383343, COSV99638877; called by muse, mutect2, varscan2
- TANC1 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs759435249, COSV55084015, COSV55098286; called by muse, mutect2, varscan2
- TAS2R10 | c.587dup p.L196Ffs*104 | Frame Shift Ins (INS) | VAF 18/84 reads (21%) | catalogued as rs1406115943; called by mutect2, varscan2
- TBC1D13 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); catalogued as rs148490755; called by muse, mutect2, varscan2
- TBC1D9 | c.3619C>T p.R1207W | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.586); catalogued as rs754331118, COSV71307494; called by muse, mutect2, varscan2
- TBRG4 | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs754537503, COSV51832661; called by muse, mutect2, varscan2
- TBX10 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372763899; called by muse, mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs763438715; called by mutect2, varscan2
- TECTA | c.1666A>G p.S556G | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV50707503; called by muse, mutect2, varscan2
- TENM2 | c.3109T>G p.S1037A (on ENST00000518659 / NM_001122679.2; = p.S805A on NM_001080428.3) | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV69130253; called by muse, mutect2, varscan2
- TEP1 | c.1664C>T p.S555L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as rs1051144201, COSV52997346; called by mutect2, varscan2
- TFB1M | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs368405074; called by muse, mutect2, varscan2
- TG | c.6131G>A p.R2044H | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.88); catalogued as rs573866267, COSV55076078; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199861425; called by muse, mutect2, varscan2
- TGM7 | c.2020C>A p.L674I | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.936); catalogued as COSV71772795, COSV71772798; called by muse, mutect2, varscan2
- THADA | c.4325A>G p.K1442R | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV57683501, COSV57691138; called by muse, mutect2, varscan2
- THBS3 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs751959993, COSV64249388; called by muse, mutect2, varscan2
- TICRR | c.3103C>T p.P1035S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV51541458; called by muse, mutect2, varscan2
- TJP3 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370766855; called by muse, mutect2, varscan2
- TLE3 | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58169442; called by muse, mutect2, varscan2
- TLX1 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.642); catalogued as COSV64622490; called by muse, mutect2, varscan2
- TM7SF3 | c.492del p.F164Lfs*6 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | catalogued as COSV100544910; called by mutect2, pindel, varscan2
- TMC4 | c.587C>T p.P196L (on ENST00000617472 / NM_001145303.3; = p.P190L on NM_144686.4) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.309); catalogued as COSV55475774; called by muse, mutect2, varscan2
- TMEM106B | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67543900, COSV67544092; called by muse, mutect2, varscan2
- TMEM132D | c.487del p.E163Rfs*6 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as COSV101398858; called by mutect2, pindel, varscan2
- TMEM63A | c.1337T>C p.M446T | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs982550757, COSV100834194; called by muse, varscan2
- TMEM87B | c.773del p.L258Wfs*27 | Frame Shift Del (DEL) | VAF 26/146 reads (18%) | catalogued as rs750138307; called by mutect2, varscan2
- TMPRSS3 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs763150678, CM154680, COSV52300609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMX3 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV55185428; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1252246458, COSV64423314; called by muse, mutect2, varscan2
- TNFRSF1A | c.40-1G>T p.X14_splice | Splice Site (SNP) | VAF 36/97 reads (37%) | catalogued as COSV99369289; called by muse, mutect2, varscan2
- TNFSF18 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 69/291 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs370771974, COSV53441216; called by muse, mutect2, varscan2
- TNKS | c.1664del p.N555Ifs*5 | Frame Shift Del (DEL) | VAF 46/185 reads (25%) | catalogued as rs200458028; called by mutect2, pindel, varscan2
- TOGARAM2 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs781395884, COSV65421532; called by muse, mutect2, varscan2
- TOPORS | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV100745209, COSV62116917; called by muse, mutect2, varscan2
- TP53BP1 | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752274598, COSV55496714; called by muse, mutect2, varscan2
- TP53I3 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51980840; called by muse, mutect2, varscan2
- TPO | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as rs199694732, CM022257, COSV61101763; called by muse, mutect2, varscan2
- TRIB2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186204534, COSV50224342; called by muse, mutect2, varscan2
- TRIM3 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV61983920; called by muse, mutect2, varscan2
- TRIM33 | c.2900A>G p.E967G | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61822584; called by muse, mutect2, varscan2
- TRIM52 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 39/136 reads (29%) | catalogued as rs758734479, COSV59844236; called by muse, mutect2, varscan2
- TRIM71 | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67470946; called by muse, mutect2, varscan2
- TRIM71 | c.2009C>A p.A670D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67470953; called by muse, mutect2
- TRIOBP | c.4478C>T p.A1493V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.06); catalogued as COSV100730485; called by mutect2, varscan2
- TRIP11 | c.5056G>T p.E1686* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV50921468; called by muse, mutect2, varscan2
- TRIP11 | c.2508G>T p.Q836H | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1185580561, COSV50921526; called by muse, mutect2, varscan2
- TRPM2 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.132); catalogued as COSV55969646; called by muse, mutect2, varscan2
- TRPV6 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.828); catalogued as rs762397125, COSV63891740; called by muse, mutect2, varscan2
- TSC2 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs45517148, CM010496, COSV54764722, COSV99552164; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- TSGA10IP | c.1441G>T p.V481F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100408779, COSV56710433; called by muse, mutect2, varscan2
- TSNAXIP1 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54649758, COSV54649777; called by muse, mutect2, varscan2
- TSPAN13 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763710458, COSV50438142; called by muse, mutect2, varscan2
- TSPAN3 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs749142832, COSV51214910; called by muse, mutect2, varscan2
- TSPAN5 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV99995157; called by muse, mutect2, varscan2
- TTC3 | c.5671A>G p.T1891A | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV61290169; called by muse, mutect2, varscan2
- TTN | c.40895A>G p.D13632G (on ENST00000591111; = p.D6208G on NM_003319.4) | Missense Mutation (SNP) | VAF 49/206 reads (24%) | PolyPhen probably damaging (0.998); catalogued as COSV60059299; called by muse, mutect2, varscan2
- TTN | c.40400G>A p.R13467Q (on ENST00000591111; = p.R6043Q on NM_003319.4) | Missense Mutation (SNP) | VAF 26/133 reads (20%) | PolyPhen benign (0.001); catalogued as rs781435431, COSV59900184; called by muse, mutect2, varscan2
- TUBB4B | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV61116668; called by muse, mutect2, varscan2
- TUBGCP2 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as rs1376717714, COSV53304356; called by muse, mutect2, varscan2
- UACA | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV59855765; called by muse, mutect2, varscan2
- UBR3 | c.3710T>C p.V1237A | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs1258337853, COSV55849402; called by muse, mutect2, varscan2
- UHRF1 | c.970C>T p.R324W (on ENST00000612630 / NM_001290050.1; = p.R337W on NM_013282.4) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1343105285, COSV99503230; called by muse, mutect2, varscan2
- UNC5B | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747312686, COSV58977174; called by muse, mutect2, varscan2
- UNC5CL | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs764324250, COSV55109879; called by muse, mutect2, varscan2
- UNC79 | c.4023C>A p.F1341L (on ENST00000393151 / NM_001346218.2; = p.F1164L on NM_020818.5) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV56387799; called by muse, mutect2, varscan2
- UPB1 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs143521220; called by muse, mutect2
- UPK1B | c.697del p.V233Lfs*53 | Frame Shift Del (DEL) | VAF 59/220 reads (27%) | catalogued as rs763060314; called by mutect2, pindel, varscan2
- UPP2 | c.713del p.K238Sfs*2 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | catalogued as rs759424183; called by mutect2, pindel, varscan2
- USP1 | c.1624T>G p.F542V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV52005452; called by muse, varscan2
- USP30 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200435024, COSV57449195; called by muse, mutect2, varscan2
- VIL1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs369865042; called by muse, mutect2, varscan2
- VIPAS39 | c.762G>T p.A254= | Splice Region (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100493058, COSV58939741; called by muse, mutect2, varscan2
- VPS13D | c.2218C>A p.L740I | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.879); catalogued as COSV50638590; called by muse, mutect2, varscan2
- VPS13D | c.5146G>A p.V1716M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV99165309; called by muse, mutect2, varscan2
- VRK2 | c.1089del p.V364Sfs*21 | Frame Shift Del (DEL) | VAF 28/132 reads (21%) | catalogued as rs768472226; called by mutect2, varscan2
- WASF1 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV63935415; called by muse, mutect2, varscan2
- WDPCP | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.426); catalogued as rs780498393, COSV55419820, COSV55435872; called by muse, mutect2, varscan2
- WDR26 | c.1039A>G p.T347A (on ENST00000414423 / NM_001379403.1; = p.T247A on NM_025160.7) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs1195820359, COSV54355417; called by muse, mutect2, varscan2
- WDTC1 | c.1675G>A p.D559N (on ENST00000319394 / NM_001276252.2; = p.D558N on NM_015023.5) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60088293; called by muse, mutect2, varscan2
- WLS | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52041089; called by muse, mutect2, varscan2
- WNT2 | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55411029; called by muse, mutect2, varscan2
- WWC1 | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1428115717, COSV54650872; called by muse, mutect2, varscan2
- YIF1A | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs759439307, COSV61012469; called by muse, mutect2, varscan2
- ZAN | c.4448del p.H1483Pfs*9 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as COSV104418999; called by mutect2, pindel, varscan2
- ZBP1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV59061782; called by muse, varscan2
- ZC3H12C | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53708828; called by muse, mutect2, varscan2
- ZCCHC14 | c.2017del p.R673Gfs*16 (on ENST00000268616; = p.R810Gfs*16 on NM_015144.3) | Frame Shift Del (DEL) | VAF 40/153 reads (26%) | catalogued as COSV51885495; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFAT | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1018621510, COSV64738544; called by muse, mutect2, varscan2
- ZFHX3 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV51709170; called by muse, mutect2, varscan2
- ZFYVE26 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs765780851, COSV61324529; called by muse, mutect2, varscan2
- ZHX2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV58713229; called by muse, mutect2, varscan2
- ZMYM5 | c.71T>C p.M24T | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV100562464; called by muse, mutect2, varscan2
- ZNF257 | c.1482A>C p.K494N | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV71307445, COSV71310216; called by muse, mutect2, varscan2
- ZNF281 | c.1958G>A p.G653D | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54167120; called by muse, mutect2, varscan2
- ZNF311 | c.970del p.T324Pfs*83 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | catalogued as COSV65853064; called by mutect2, varscan2
- ZNF324B | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.153); catalogued as rs371148383; called by muse, mutect2, varscan2
- ZNF354C | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs545360275, COSV59608306, COSV59609768; called by muse, mutect2, varscan2
- ZNF362 | c.696C>G p.C232W | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65031425; called by muse, mutect2, varscan2
- ZNF382 | c.1381dup p.E461Gfs*7 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | catalogued as rs1555793855; called by mutect2, pindel
- ZNF395 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs142226591, COSV60428576; called by muse, mutect2, varscan2
- ZNF483 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV58515510; called by muse, mutect2, varscan2
- ZNF483 | c.1794G>T p.Q598H | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.856); catalogued as COSV58514785; called by muse, mutect2, varscan2
- ZNF488 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs138808688; called by muse, mutect2, varscan2
- ZNF536 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs755632176, COSV62829545; called by muse, mutect2, varscan2
- ZNF569 | c.226A>T p.R76* | Nonsense Mutation (SNP) | VAF 23/192 reads (12%) | catalogued as COSV57595380; called by muse, mutect2, varscan2
- ZNF629 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV52698535; called by muse, mutect2, varscan2
- ZNF646 | c.4678C>A p.L1560M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.592); catalogued as COSV99761912; called by muse, mutect2, varscan2
- ZNF684 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV65519092; called by muse, mutect2, varscan2
- ZNF704 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59922945; called by muse, mutect2, varscan2
- ZNF785 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV67876330; called by muse, mutect2, varscan2
- ZNF792 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68693245; called by muse, mutect2, varscan2
- ZNF793 | c.531T>A p.N177K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV71324978; called by muse, mutect2, varscan2
- ZP1 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs759405234, COSV53924336; called by muse, mutect2, varscan2
- ZSCAN25 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs190565948, COSV99500352; called by mutect2, varscan2
- ABCB9 | c.1682del p.G561Afs*21 (on ENST00000280560 / NM_019625.4; = p.G518Afs*21 on NM_019624.3) | Frame Shift Del (DEL) | VAF 36/93 reads (39%) | called by mutect2, pindel, varscan2
- ADAM7 | c.1781del p.L594Yfs*29 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.2311G>C p.A771P | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADHFE1 | c.209del p.N70Tfs*9 | Frame Shift Del (DEL) | VAF 32/150 reads (21%) | called by mutect2, pindel, varscan2
- AFM | c.35dup p.F14Vfs*5 | Frame Shift Ins (INS) | VAF 32/129 reads (25%) | called by mutect2, varscan2
- AKAP12 | c.1810del p.R604Efs*14 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, varscan2
- AKAP5 | c.412del p.R138Gfs*8 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- ALOX12B | c.1446dup p.N483Qfs*2 | Frame Shift Ins (INS) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- ANGPTL2 | c.81del p.F27Lfs*15 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
397 further variants in this file (135 protein-altering or splice-affecting, 244 silent, 18 other) are not listed here.
